Somatic mutation profile of tumor specimen TCGA-3C-AAAU-01A (aliquot TCGA-3C-AAAU-01A-11D-A41F-09) from TCGA case TCGA-3C-AAAU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 55.3 years (20,211 days).
Specimen TCGA-3C-AAAU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b784d7f-941b-4736-bdcb-a296d9ccd946.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3C-AAAU-10A (Blood Derived Normal), aliquot TCGA-3C-AAAU-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b867a860-ac5b-470a-b5a3-dcdb865b0975

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Splice Site 2, Splice Region 2, Frame Shift Ins 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.3843C>T p.N1281= | Splice Region (SNP) | VAF 8/36 reads (22%) | catalogued as rs775988507, COSV100673488; called by muse, mutect2, varscan2
- CCT6A | c.1523+2T>C p.X508_splice | Splice Site (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99303769; called by muse, mutect2, varscan2
- CSMD1 | c.2904A>G p.G968= (on ENST00000520002; = p.G967= on NM_033225.6) | Splice Region (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100153617; called by muse, mutect2, varscan2
- DDAH1 | c.598-2A>T p.X200_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99395333; called by muse, mutect2, varscan2
- FAM71B | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as rs370119273; called by muse, mutect2, varscan2
- GATA3 | c.1220_1221insA p.P408Afs*99 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as COSV100650835, COSV100651341, COSV60515158, COSV60515274, COSV60515375, COSV60517941; called by mutect2, pindel, varscan2
- GYG2 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750258006, COSV58549589; called by muse, mutect2, varscan2
- MAN1B1 | c.1607G>A p.G536D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100857424; called by muse, mutect2, varscan2
- MIPOL1 | c.892A>G p.M298V | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs756594798, COSV59378824; called by muse, mutect2, varscan2
- PLG | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV51983627, COSV99805118; called by muse, mutect2, varscan2
- PTCHD1 | c.2606A>G p.E869G | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1348876609, COSV101038004; called by muse, mutect2, varscan2
- RPL18 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99320396; called by muse, mutect2, varscan2
- SRBD1 | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99765561; called by muse, mutect2, varscan2
- TGFB1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1046906328, COSV99700294; called by mutect2, varscan2
- THSD4 | c.2197C>G p.L733V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV99967072; called by muse, mutect2, varscan2
- ZEB2 | c.2669G>A p.S890N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV100356891; called by muse, mutect2, varscan2
- CDR2L | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- EP300 | c.4015_4016dup p.M1339Ifs*2 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- DNAI1 | c.780G>A p.K260= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99647160; called by muse, mutect2, varscan2
- GLIS2 | c.57G>A p.A19= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs199506809, COSV52111912; called by muse, mutect2, varscan2
- ITGAM | c.2238C>T p.F746= (on ENST00000648685 / NM_001145808.2; = p.F745= on NM_000632.4) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs747905386, COSV99791568; called by muse, mutect2, varscan2
- KDM1A | c.2558G>A p.*853= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100174198; called by muse, mutect2
- ULK3 | c.1176C>T p.A392= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs543123189, COSV101475560; called by muse, mutect2, varscan2
- WDR24 | c.1611C>T p.G537= (on ENST00000248142; = p.G407= on NM_032259.4) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs779458750, COSV50197916; called by muse, mutect2, varscan2
- XIRP2 | c.63G>A p.E21= (on ENST00000628543; = p.E196= on NM_152381.6) | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV54727643; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505435 del AAA | 5'Flank (DEL) | VAF 21/75 reads (28%) | catalogued as rs747294826; called by mutect2, pindel, varscan2
